Somatic mutation profile of tumor specimen C3N-02030-03 (aliquot CPT0133780085) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a07ee0b8-6bea-42d4-968d-237fcd094308.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35444a2c-c372-4dc2-af72-f781e9aa7096

The open-access MAF lists 724 somatic variants for this specimen: 496 protein-altering or splice-affecting, 143 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 344, Silent 143, Frame Shift Del 92, Intron 50, Frame Shift Ins 23, Nonsense Mutation 20, 3'UTR 10, RNA 10, 5'UTR 7, Splice Region 6, 3'Flank 5, Splice Site 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 21/174 reads (12%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 143/301 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 50/105 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 132/344 reads (38%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 108/296 reads (36%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PRPF6 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs387907100, CM112959, COSV53868700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 138/289 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 100/221 reads (45%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, mutect2, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 62/196 reads (32%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ABI3 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs770714352; called by muse, mutect2, varscan2
- ACTN4 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs758778538; called by muse, mutect2, varscan2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 120/183 reads (66%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AHRR | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 31/578 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs778268200, COSV57086110; called by muse, mutect2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 60/163 reads (37%) | catalogued as rs765201611; called by mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- ALG5 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53504362; called by muse, mutect2
- AOX1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs769661664; called by muse, mutect2, varscan2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 243/537 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 112/338 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- AXL | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV99997218; called by muse, mutect2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 67/194 reads (35%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GAT1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763308287; called by muse, mutect2, varscan2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD2 | c.1932C>A p.Y644* | Nonsense Mutation (SNP) | VAF 105/262 reads (40%) | catalogued as COSV100875888; called by muse, mutect2, varscan2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CCDC190 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373634463; called by muse, mutect2, varscan2
- CCDC80 | c.1982C>T p.T661I | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1559880379, COSV52816132; called by muse, mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | catalogued as rs759091263; called by mutect2, varscan2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 213/557 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 18/61 reads (30%) | catalogued as rs768479535; called by mutect2, pindel
- CFAP206 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1333669635; called by muse, mutect2
- CLDN12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 102/274 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55307631; called by muse, mutect2, varscan2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 34/77 reads (44%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2, varscan2
- COL7A1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 170/461 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778104401; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPSF6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs753465837; called by muse, mutect2, varscan2
- CRACD | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs776911167, COSV51728777; called by muse, mutect2
- CREM | c.364A>G p.R122G (on ENST00000429130; = p.R73G on NM_001881.3) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188189426; called by muse, mutect2, varscan2
- CRISPLD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 92/241 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs372363505; called by muse, mutect2, varscan2
- CROCC | c.3604C>T p.R1202* | Nonsense Mutation (SNP) | VAF 31/179 reads (17%) | catalogued as COSV65011597; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2, varscan2
- D2HGDH | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1472114573, COSV58319342; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 171/375 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DCC | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as COSV59092602; called by muse, mutect2
- DCHS1 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 161/343 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs772193454; called by muse, mutect2, varscan2
- DDX46 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62798529; called by muse, mutect2
- DIAPH3 | c.3497del p.K1166Rfs*49 | Frame Shift Del (DEL) | VAF 53/312 reads (17%) | catalogued as rs749399334, COSV100931069; called by mutect2, pindel, varscan2
- DKK4 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs764520274, COSV55183577; called by muse, mutect2, varscan2
- DLEC1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 149/325 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs780446743, COSV57300501; called by muse, mutect2, varscan2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 140/539 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DOCK1 | c.5210G>A p.R1737Q | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1465060783; called by muse, mutect2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 42/100 reads (42%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DRC3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs757392054; called by muse, mutect2, varscan2
- DSCAM | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs367647810, COSV101259937; called by muse, mutect2, varscan2
- DYNC1LI2 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs1184501423; called by muse, mutect2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 43/86 reads (50%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EML3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1465554218; called by muse, mutect2, varscan2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2, varscan2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 158/392 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM186A | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765273273; called by muse, mutect2, varscan2
- FBP2 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1263431898; called by muse, mutect2, varscan2
- FBXO16 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV60775614; called by muse, mutect2
- FEV | c.704dup p.H236Pfs*18 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs141171754; called by mutect2, pindel, varscan2
- FKBP8 | c.779C>T p.T260M (on ENST00000222308 / NM_001308373.2; = p.T261M on NM_012181.5) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55893476; called by muse, varscan2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 259/676 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC2 | c.275_277del p.K92del | In Frame Del (DEL) | VAF 281/778 reads (36%) | catalogued as rs1203250715; called by pindel, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 113/328 reads (34%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- GJA5 | c.139del p.D47Mfs*112 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | catalogued as rs782528459, COSV54784545; called by mutect2, pindel, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 34/112 reads (30%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1394891575; called by muse, mutect2, varscan2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPR137B | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs147078955; called by muse, mutect2, varscan2
- HECA | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1562248450, COSV62769077; called by muse, mutect2
- HNRNPA1 | c.18T>G p.S6= | Splice Region (SNP) | VAF 31/84 reads (37%) | catalogued as rs755898648; called by muse, mutect2, varscan2
- HSD17B4 | c.1679G>A p.C560Y (on ENST00000414835 / NM_001199291.3; = p.C535Y on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56335900; called by muse, mutect2, varscan2
- HSPA12A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781809567; called by muse, mutect2, varscan2
- ICE1 | c.6169C>T p.R2057C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1329448263, COSV56822031; called by muse, mutect2, varscan2
- INPP4A | c.2930C>T p.T977M (on ENST00000074304 / NM_001134224.1; = p.T938M on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559132688, COSV50789938; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 32/75 reads (43%) | catalogued as rs755650243; called by mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 68/182 reads (37%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KHDC1 | c.581G>A p.S194N (on ENST00000370384 / NM_001251874.2; = p.S121N on NM_030568.5) | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.916); catalogued as rs962762004, COSV57615383; called by muse, mutect2, varscan2
- KIF26B | c.4157C>A p.P1386H | Missense Mutation (SNP) | VAF 34/465 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV63639112; called by muse, mutect2
- KIF2B | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV99274473; called by muse, mutect2, varscan2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2, varscan2
- KMT2B | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755245377; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, mutect2, varscan2
- KMT2D | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56468464; called by muse, mutect2, varscan2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LANCL2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs770121457, COSV54649883; called by muse, mutect2, varscan2
- LILRB5 | c.1526G>A p.G509D (on ENST00000449561 / NM_001081442.3; = p.G508D on NM_006840.5) | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV60260780; called by muse, mutect2, varscan2
- LIN37 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs754704937, COSV50001208; called by muse, mutect2
- LRP2 | c.11013C>T p.C3671= | Splice Region (SNP) | VAF 44/349 reads (13%) | catalogued as rs1436494910, COSV99789716; called by muse, mutect2, varscan2
- LRRC53 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs937695676, COSV53946315; called by muse, mutect2
- MACROH2A2 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV64712555; called by muse, mutect2, varscan2
- MAGIX | c.958dup p.A320Gfs*88 | Frame Shift Ins (INS) | VAF 48/132 reads (36%) | catalogued as rs1321319432; called by mutect2, pindel
- MAML3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1171552463; called by muse, mutect2, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 124/278 reads (45%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MAP4K4 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56336408; called by muse, mutect2, varscan2
- MIB2 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 23/235 reads (10%) | catalogued as rs748579075, COSV61755718; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MKRN3 | c.443A>G p.H148R | Missense Mutation (SNP) | VAF 31/361 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs148583347; called by muse, mutect2
- MRC2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 95/299 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640762; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 147/401 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 44/192 reads (23%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NMD3 | c.-20-8_-20-5del | Splice Region (DEL) | VAF 21/76 reads (28%) | catalogued as rs1211145199; called by mutect2, varscan2*
- NOTCH1 | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 198/477 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53082811; called by muse, mutect2, varscan2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- NUP188 | c.4997C>T p.A1666V | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs529060637, COSV65330012; called by muse, mutect2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 42/111 reads (38%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OGA | c.1578del p.M527Cfs*27 | Frame Shift Del (DEL) | VAF 100/400 reads (25%) | catalogued as COSV63382218; called by mutect2, pindel, varscan2
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 121/288 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR13G1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1558292655; called by muse, mutect2, varscan2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 125/326 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, mutect2, varscan2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 85/263 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OR6C4 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs750194566; called by muse, mutect2, varscan2
- OTUD7B | c.1976del p.G659Vfs*169 | Frame Shift Del (DEL) | VAF 45/253 reads (18%) | catalogued as COSV100967422; called by mutect2, pindel, varscan2
- P3H2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1310957916; called by muse, mutect2, varscan2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 60/140 reads (43%) | catalogued as rs767894241; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA13 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs891112880, COSV56510270; called by muse, mutect2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 105/304 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | catalogued as rs1262793592; called by mutect2, pindel, varscan2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDPN | c.41C>T p.A14V (on ENST00000621990; = p.A90V on NM_006474.4) | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.678); catalogued as COSV53848837; called by muse, mutect2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | catalogued as rs759495724; called by mutect2, varscan2
- PEAK1 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 36/257 reads (14%) | catalogued as rs538475609, COSV56935136; called by muse, mutect2, varscan2
- PGAP6 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758802749; called by muse, mutect2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PI4KA | c.5219A>G p.K1740R | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1390556648, COSV55402756; called by muse, mutect2
- PI4KA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1460046498, COSV55412316, COSV55422086; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PKP3 | c.2260_2262del p.K754del | In Frame Del (DEL) | VAF 36/113 reads (32%) | catalogued as rs755089774; called by pindel, varscan2
- PLCB4 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as rs1347474766, COSV53807281; called by muse, mutect2, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 91/298 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- PMFBP1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as rs1480138422; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3GL | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs370170498; called by muse, mutect2, varscan2
- POLRMT | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1252259962; called by muse, mutect2
- PPP4R2 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1230961376; called by muse, mutect2, varscan2
- PRDM13 | c.1869C>A p.H623Q | Missense Mutation (SNP) | VAF 250/560 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375460946; called by muse, mutect2, varscan2
- PTH1R | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 206/501 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752454624, COSV57315208; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 46/144 reads (32%) | catalogued as rs1234606471; called by mutect2, varscan2
- RASIP1 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs1472624137, COSV55808826; called by muse, mutect2, varscan2
- RASSF4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as rs748139811; called by muse, mutect2, varscan2
- RDH11 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs563954790, COSV101191426; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF213 | c.9917C>T p.T3306M | Missense Mutation (SNP) | VAF 46/566 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs147152819; called by muse, mutect2
- RNF39 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.94); PolyPhen benign (0.134); catalogued as rs773266930; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs763290832; called by mutect2, varscan2
- SBSPON | c.793T>C p.*265Qext*4 | Nonstop Mutation (SNP) | VAF 11/135 reads (8%) | catalogued as rs751517410; called by muse, mutect2
- SCARB2 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1004780277; ClinVar: uncertain significance; called by muse, mutect2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs1270083658; called by mutect2, pindel
- SGF29 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 31/636 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs1324158167, COSV100187093, COSV57681012; called by muse, mutect2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 109/257 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 42/112 reads (38%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SKIV2L | c.1637del p.G546Afs*83 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | catalogued as COSV64814087; called by mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 65/262 reads (25%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC2A11 | c.895G>A p.V299M (on ENST00000345044 / NM_001024938.4; = p.V306M on NM_030807.5) | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs773866178; called by muse, mutect2, varscan2
- SLC43A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs746970383; called by muse, mutect2, varscan2
- SLC4A4 | c.1135G>A p.V379I (on ENST00000264485 / NM_001098484.3; = p.V335I on NM_003759.4) | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs781031046; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 23/42 reads (55%) | catalogued as rs763364024; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SPATC1L | c.580C>T p.R194C (on ENST00000291672 / NM_001142854.2; = p.R40C on NM_032261.5) | Missense Mutation (SNP) | VAF 100/233 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751537273; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 40/130 reads (31%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPEN | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 155/384 reads (40%) | catalogued as rs1307834195, COSV65365281; called by muse, mutect2, varscan2
- SPEN | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs763959899, COSV65359777; called by muse, varscan2
- SPSB4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776085694, COSV60150454; called by muse, mutect2, varscan2
- SPTA1 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 132/558 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs752468147; called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SRRM1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1266741422; called by muse, mutect2, varscan2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 33/86 reads (38%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 46/119 reads (39%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TENT5B | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56693344; called by muse, mutect2, varscan2
- TET2 | c.2511T>A p.N837K | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755404521; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 141/271 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TMEM184B | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 112/289 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62672464; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs770800449; called by mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRBV29-1 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1364028234; called by muse, mutect2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 129/348 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRIOBP | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 20/145 reads (14%) | catalogued as rs1328461856, CM154690; called by muse, mutect2
- TRPV1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903705338, COSV51518182; called by muse, mutect2, varscan2
- TSPOAP1 | c.5552G>A p.R1851K | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs769282338, COSV52116577; called by muse, mutect2, varscan2
- TUBA3D | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 152/275 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.203); catalogued as rs745718611, COSV58312359; called by muse, mutect2, varscan2
- USP33 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs749382743, COSV62468280; called by muse, mutect2, varscan2
- VANGL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100925573; called by muse, mutect2, varscan2
- VSX2 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886042716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWF | c.1336G>A p.V446I | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs767209816; called by muse, mutect2
- WDFY3 | c.5723G>A p.R1908H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1217913024, COSV104399957; called by muse, mutect2
- WDFY4 | c.7295G>A p.C2432Y | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1214976776; called by muse, mutect2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 127/410 reads (31%) | catalogued as rs779864368; called by pindel, varscan2
- ZBED2 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as COSV51920425; called by muse, mutect2, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 57/146 reads (39%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZBTB25 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1346746094; called by muse, mutect2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 43/114 reads (38%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFP64 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 23/337 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV53804665; called by muse, mutect2
- ZFYVE27 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs927949688; called by muse, mutect2
- ZNF142 | c.3758G>A p.R1253H (on ENST00000411696 / NM_001379660.1; = p.R1053H on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs200582262; called by muse, mutect2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2, varscan2
- ZNF512B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs768660385, COSV53871876; called by muse, mutect2, varscan2
- ZNF697 | c.1547del p.T516Rfs*66 | Frame Shift Del (DEL) | VAF 90/273 reads (33%) | catalogued as COSV70284359; called by mutect2, pindel, varscan2
- ZNF835 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 25/329 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1568524246, COSV73379416; called by muse, mutect2
- AC004922.1 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- AC013489.1 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 239/535 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACBD3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM4 | c.990del p.D331Tfs*14 | Frame Shift Del (DEL) | VAF 20/194 reads (10%) | called by mutect2, pindel, varscan2
- ACTN4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 173/434 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.902del p.N301Ifs*4 | Frame Shift Del (DEL) | VAF 48/141 reads (34%) | called by mutect2, varscan2
- ADAM30 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY3 | c.2186A>G p.Q729R | Missense Mutation (SNP) | VAF 103/208 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- AOC3 | c.957A>C p.Q319H | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- APBB2 | c.1553A>T p.K518I (on ENST00000295974 / NM_001166050.2; = p.K519I on NM_004307.2) | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ARAP3 | c.1180del p.R394Dfs*21 | Frame Shift Del (DEL) | VAF 84/210 reads (40%) | called by mutect2, pindel, varscan2
- ARID1A | c.879del p.T294Pfs*69 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- ARID1A | c.1079C>A p.A360E | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.353); called by muse, mutect2
- ARID1A | c.3714del p.A1239Lfs*30 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 25/93 reads (27%) | called by mutect2, pindel, varscan2
- ARID5A | c.1772dup p.N591Kfs*33 | Frame Shift Ins (INS) | VAF 95/239 reads (40%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- BOD1 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BSCL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 153/385 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C2CD4D | c.231del p.A78Rfs*161 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- CATSPERE | c.1551A>G p.I517M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBX2 | c.977dup p.H329Afs*84 | Frame Shift Ins (INS) | VAF 44/121 reads (36%) | called by mutect2, pindel, varscan2
- CCDC134 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- CCDC189 | c.204+2T>C p.X68_splice | Splice Site (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- CCDC3 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CCDC85C | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 122/301 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CD6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CDH17 | c.1504del p.V502Lfs*13 | Frame Shift Del (DEL) | VAF 40/111 reads (36%) | called by mutect2, pindel, varscan2
- CDK5R2 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 32/803 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.184); called by muse, mutect2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP78 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CGA | c.158T>C p.M53T | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- CHST7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 108/255 reads (42%) | called by muse, mutect2, varscan2
- CILP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 58/165 reads (35%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 117/299 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX10 | c.1115_1116insA p.V373Cfs*92 | Frame Shift Ins (INS) | VAF 89/243 reads (37%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.3473C>T p.A1158V (on ENST00000651564; = p.A1111V on NM_015692.5) | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2
- CRAMP1 | c.1938dup p.A647Rfs*29 | Frame Shift Ins (INS) | VAF 47/147 reads (32%) | called by mutect2, pindel, varscan2
- CRAT | c.1867del p.R623Gfs*47 | Frame Shift Del (DEL) | VAF 45/250 reads (18%) | called by mutect2, pindel, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CRY2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSMD3 | c.9577C>T p.Q3193* (on ENST00000297405 / NM_001363185.1; = p.Q3024* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 83/253 reads (33%) | called by muse, mutect2, varscan2
- CYTH2 | c.1134C>A p.D378E (on ENST00000427476; = p.D377E on NM_004228.7) | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DAAM1 | c.2663+4_2663+7del p.X888_splice | Splice Site (DEL) | VAF 16/36 reads (44%) | called by pindel, varscan2
- DCHS1 | c.2618del p.P873Qfs*5 | Frame Shift Del (DEL) | VAF 134/353 reads (38%) | called by mutect2, pindel, varscan2
- DDR2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 106/567 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DIP2A | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAH9 | c.4961T>C p.L1654P | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- DNAJB11 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 91/188 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNAJC6 | c.2393del p.K798Rfs*6 | Frame Shift Del (DEL) | VAF 18/159 reads (11%) | called by mutect2, pindel, varscan2
- DNHD1 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- DPH2 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- E2F8 | c.1433del p.P478Qfs*2 | Frame Shift Del (DEL) | VAF 68/198 reads (34%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.136del p.T46Hfs*24 (on ENST00000531967 / NM_001139510.1; = p.T40Hfs*24 on NM_018479.3) | Frame Shift Del (DEL) | VAF 44/138 reads (32%) | called by mutect2, pindel, varscan2
- EEPD1 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- EFCAB5 | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.085); called by mutect2, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/110 reads (35%) | called by mutect2, pindel, varscan2
- ENKD1 | c.882C>T p.S294= | Splice Region (SNP) | VAF 31/170 reads (18%) | called by muse, mutect2, varscan2
- EP400 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- EPC2 | c.207del p.E70Rfs*39 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- EPC2 | c.2086C>T p.L696F | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ERICH3 | c.2296del p.T766Rfs*23 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel
- ESYT1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFRF1 | c.128del p.N43Tfs*4 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- FAM124A | c.1250G>A p.G417D (on ENST00000322475 / NM_001242312.2; = p.G453D on NM_145019.4) | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM53C | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- FASTKD5 | c.1547C>T p.T516I | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 198/478 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBP2 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 19/360 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2
- FBXO32 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 56/196 reads (29%) | called by pindel, varscan2*
- FCSK | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 119/319 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FLAD1 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 19/448 reads (4%) | PolyPhen benign (0); called by muse, mutect2
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 63/236 reads (27%) | called by mutect2, pindel, varscan2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 60/204 reads (29%) | called by pindel, varscan2
- FSIP2 | c.20722T>C p.*6908Rext*5 | Nonstop Mutation (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2
- FTO | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 110/243 reads (45%) | called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRA6 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 142/343 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT7 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GFRA4 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2
- GLI3 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 121/296 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GMNN | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- GON4L | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 161/681 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPHN | c.1382G>A p.G461D (on ENST00000315266 / NM_001377519.1; = p.G494D on NM_020806.5) | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 60/207 reads (29%) | called by mutect2, pindel, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 84/212 reads (40%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC1 | c.14137C>T p.P4713S | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERPUD2 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- HGS | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HIVEP1 | c.6791A>G p.Q2264R | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 55/187 reads (29%) | called by pindel, varscan2
- HMCN1 | c.10119G>T p.Q3373H | Missense Mutation (SNP) | VAF 17/510 reads (3%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); called by muse, mutect2
- HOXA5 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 195/442 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- HYDIN | c.12622A>C p.N4208H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGF1R | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL3RA | c.898_901del p.N300Hfs*9 | Frame Shift Del (DEL) | VAF 86/223 reads (39%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2337_2339del p.K779_S780delinsN | In Frame Del (DEL) | VAF 35/91 reads (38%) | called by mutect2, pindel, varscan2
- IRS2 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 118/270 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, varscan2
- IRX2 | c.305dup p.Y103Vfs*87 | Frame Shift Ins (INS) | VAF 16/162 reads (10%) | called by mutect2, pindel
- ITGA6 | c.276del p.P93Hfs*37 | Frame Shift Del (DEL) | VAF 175/469 reads (37%) | called by mutect2, varscan2
- JADE1 | c.803T>C p.M268T | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 50/156 reads (32%) | called by mutect2, pindel, varscan2
- JAM3 | c.240del p.F80Lfs*21 | Frame Shift Del (DEL) | VAF 97/285 reads (34%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- JMJD4 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 72/856 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.54); called by muse, mutect2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 136/340 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, varscan2
- KCNC4 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 21/361 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- KDM2B | c.2594del p.F865Sfs*69 | Frame Shift Del (DEL) | VAF 14/126 reads (11%) | called by mutect2, pindel, varscan2
- KDM4B | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 176/877 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLHL13 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KLHL26 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL29 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 47/120 reads (39%) | called by muse, mutect2, varscan2
- KRI1 | c.1654T>C p.C552R | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LAMP1 | c.818T>G p.L273R | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.076); called by muse, mutect2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 76/229 reads (33%) | called by mutect2, pindel, varscan2
- LDLR | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.997dup p.S333Ffs*12 | Frame Shift Ins (INS) | VAF 27/72 reads (38%) | called by mutect2, pindel, varscan2
- LRRC73 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2
- LYST | c.8494A>G p.S2832G | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B1 | c.2178del p.K727Rfs*39 | Frame Shift Del (DEL) | VAF 140/409 reads (34%) | called by mutect2, pindel, varscan2
- MAP1B | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- MDC1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 116/253 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 192/476 reads (40%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MGRN1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 117/322 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKNK2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MLH3 | c.3509T>C p.V1170A | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MPHOSPH8 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MYLK | c.2722A>G p.K908E | Missense Mutation (SNP) | VAF 28/768 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2
- NAV3 | c.7153C>A p.L2385I (on ENST00000397909 / NM_001024383.2; = p.L2363I on NM_014903.6) | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NECAB1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFRKB | c.406C>A p.L136I (on ENST00000446488 / NM_001143835.2; = p.L149I on NM_006165.3) | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NHS | c.1462del p.R488Gfs*68 | Frame Shift Del (DEL) | VAF 61/176 reads (35%) | called by mutect2, pindel, varscan2
- NOL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOTCH1 | c.7625G>A p.S2542N | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.309); called by muse, mutect2
- NPR3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRTN | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 13/420 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 88/242 reads (36%) | called by mutect2, varscan2
- NUP214 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUP42 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 42/135 reads (31%) | called by mutect2, pindel, varscan2
- OR2C1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- OTOG | c.5639del p.P1880Qfs*99 | Frame Shift Del (DEL) | VAF 120/349 reads (34%) | called by mutect2, pindel, varscan2
- P2RX2 | c.869C>A p.P290H (on ENST00000343948 / NM_170683.4; = p.P218H on NM_012226.5) | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA2 | c.82+2T>A p.X28_splice | Splice Site (SNP) | VAF 47/118 reads (40%) | called by muse, mutect2, varscan2
- PAPOLA | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PAPSS1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 142/344 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PBX3 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB5 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.213); called by muse, mutect2
- PCDHGA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA3 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 207/512 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 171/348 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.2091del p.F697Lfs*3 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- PDPR | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 97/386 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PIGB | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- PIGQ | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PIK3AP1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PLEKHF1 | c.814del p.V272Wfs*88 | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | called by mutect2, pindel, varscan2
- PLEKHO1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); called by muse, mutect2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 214/425 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 81/226 reads (36%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | called by mutect2, pindel, varscan2
- PRR14L | c.5514del p.K1838Nfs*16 | Frame Shift Del (DEL) | VAF 34/204 reads (17%) | called by mutect2, pindel, varscan2
- PTK7 | c.1320dup p.P441Tfs*35 | Frame Shift Ins (INS) | VAF 63/169 reads (37%) | called by mutect2, pindel, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 34/87 reads (39%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 127/318 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- RASAL2 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBL1 | c.824T>G p.I275S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RBPJ | c.663del p.F221Lfs*42 | Frame Shift Del (DEL) | VAF 41/103 reads (40%) | called by mutect2, pindel, varscan2
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIPK3 | c.1092del p.K364Nfs*69 | Frame Shift Del (DEL) | VAF 48/282 reads (17%) | called by mutect2, pindel, varscan2
- RLIM | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | called by mutect2, varscan2
- RPE | c.620G>T p.R207I (on ENST00000359429 / NM_001318926.1; = p.R157I on NM_006916.2) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS6KA6 | c.2076T>G p.D692E | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SAG | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 249/562 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN3 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 90/211 reads (43%) | called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 40/48 reads (83%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- SGK1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH2D3C | c.2087A>G p.Q696R (on ENST00000314830 / NM_170600.3; = p.Q539R on NM_005489.4) | Missense Mutation (SNP) | VAF 6/164 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 281/677 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, varscan2
- SI | c.2078A>G p.Y693C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SLC38A10 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, varscan2
- SLC9A2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A5 | c.1555C>A p.R519S | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SORCS3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 112/396 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SPTBN2 | c.5705T>A p.L1902Q | Missense Mutation (SNP) | VAF 24/429 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2
- SRCAP | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2
- SSC5D | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 110/295 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- STK35 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- STOX1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- STOX2 | c.2423G>T p.R808L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by muse, mutect2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 77/250 reads (31%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1903del p.M635Cfs*26 (on ENST00000367255 / NM_182961.4; = p.M642Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 120/372 reads (32%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5005dup p.M1669Nfs*8 | Frame Shift Ins (INS) | VAF 29/103 reads (28%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 215/527 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TARBP2 | c.176A>G p.Q59R (on ENST00000266987 / NM_134323.2; = p.Q38R on NM_004178.4) | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.26); called by muse, mutect2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TCF19 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TCP11X1 | c.832del p.A278Qfs*19 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- TENT5A | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.174); called by muse, mutect2
- TEX11 | c.562G>A p.A188T (on ENST00000344304; = p.A173T on NM_031276.3) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TINAG | c.296dup p.S100Vfs*5 | Frame Shift Ins (INS) | VAF 43/129 reads (33%) | called by mutect2, pindel, varscan2
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 92/260 reads (35%) | called by mutect2, pindel, varscan2
- TMEM260 | c.941+3A>G | Splice Region (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- TMEM62 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRAPPC6A | c.283C>A p.L95M (on ENST00000585934 / NM_001270891.2; = p.L109M on NM_024108.3) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM35 | c.1403del p.G468Vfs*129 | Frame Shift Del (DEL) | VAF 23/189 reads (12%) | called by mutect2, pindel, varscan2
- TRIM41 | c.1806C>A p.H602Q | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM64C | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 113/259 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM72 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRMT2A | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC37 | c.3758del p.N1253Ifs*4 | Frame Shift Del (DEL) | VAF 74/225 reads (33%) | called by mutect2, pindel, varscan2
- TTN | c.99470del p.K33157Sfs*12 (on ENST00000591111; = p.K25733Sfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 84/206 reads (41%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 68/200 reads (34%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UQCR10 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP47 | c.1205G>T p.R402M (on ENST00000399455 / NM_001372095.1; = p.R314M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XPR1 | c.809G>T p.R270I | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- YIPF7 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- ZBTB1 | c.1571dup p.Q525Afs*4 | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | called by mutect2, varscan2
- ZBTB11 | c.2626C>T p.H876Y | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 44/137 reads (32%) | called by mutect2, pindel, varscan2
- ZIC5 | c.497del p.P166Lfs*165 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- ZNF292 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF438 | c.2085G>T p.Q695H | Missense Mutation (SNP) | VAF 21/467 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ACSF3 | c.1197C>T p.C399= | Silent (SNP) | VAF 42/208 reads (20%) | catalogued as rs768148002; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADSL | c.1449T>C p.C483= | Silent (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- AFF2 | c.1902T>C p.V634= | Silent (SNP) | VAF 15/235 reads (6%) | called by muse, mutect2
- AHNAK | c.14412G>A p.L4804= | Silent (SNP) | VAF 101/268 reads (38%) | called by muse, mutect2, varscan2
- ANHX | c.636G>A p.A212= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs565245948; called by muse, mutect2, varscan2
- APC2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs1308241401; called by muse, mutect2, varscan2
- ARHGEF17 | c.5055G>A p.E1685= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as rs1016884567; called by muse, mutect2
- ARID1A | c.1077C>T p.H359= | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 70/186 reads (38%) | called by muse, mutect2, varscan2
- B3GNT9 | c.864C>T p.G288= | Silent (SNP) | VAF 68/157 reads (43%) | catalogued as rs1462443365; called by muse, mutect2, varscan2
- BICRA | c.3603C>T p.Y1201= | Silent (SNP) | VAF 28/316 reads (9%) | catalogued as rs1177638988; called by muse, mutect2
- BRWD3 | c.5058C>T p.G1686= | Silent (SNP) | VAF 77/186 reads (41%) | catalogued as rs781010314; called by muse, mutect2, varscan2
- C10orf120 | c.549A>G p.L183= | Silent (SNP) | VAF 43/152 reads (28%) | called by muse, mutect2, varscan2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 155/373 reads (42%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CACNA1E | c.6783C>T p.G2261= (on ENST00000367573 / NM_001205293.3; = p.G2218= on NM_000721.4) | Silent (SNP) | VAF 7/167 reads (4%) | catalogued as COSV62381538; called by muse, mutect2
- CALB1 | c.18G>A p.L6= | Silent (SNP) | VAF 13/254 reads (5%) | catalogued as COSV55370434; called by muse, mutect2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 69/200 reads (35%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1683G>A p.R561= | Silent (SNP) | VAF 86/223 reads (39%) | called by muse, mutect2, varscan2
- CBX8 | c.57G>A p.R19= | Silent (SNP) | VAF 87/223 reads (39%) | catalogued as rs1221350080; called by muse, mutect2, varscan2
- CCDC8 | c.345C>T p.D115= | Silent (SNP) | VAF 46/252 reads (18%) | catalogued as rs1290525774; called by muse, mutect2, varscan2
- CCNB3 | c.2943C>T p.A981= | Silent (SNP) | VAF 9/236 reads (4%) | catalogued as COSV52078472; called by muse, mutect2
- CD1E | c.849G>A p.L283= | Silent (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- CD81 | c.396G>A p.Q132= | Silent (SNP) | VAF 241/538 reads (45%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 65/156 reads (42%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- COL4A6 | c.1248C>T p.G416= | Silent (SNP) | VAF 102/260 reads (39%) | called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 152/373 reads (41%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- CUBN | c.10632T>C p.P3544= | Silent (SNP) | VAF 30/543 reads (6%) | called by muse, mutect2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- CYSLTR1 | c.471A>G p.P157= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs1204079251; called by muse, mutect2, varscan2
- DAXX | c.276G>A p.Q92= | Silent (SNP) | VAF 70/184 reads (38%) | catalogued as COSV56472142; called by muse, mutect2, varscan2
- DDB1 | c.2562G>A p.S854= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as rs771383564; called by muse, mutect2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 69/164 reads (42%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DLX4 | c.27C>T p.P9= | Silent (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- DST | c.11112G>A p.V3704= (on ENST00000361203 / NM_001374722.1; = p.V1292= on NM_015548.5) | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs772436994; called by muse, mutect2, varscan2
- DTX3L | c.2004G>A p.K668= | Silent (SNP) | VAF 37/247 reads (15%) | catalogued as rs181955910; called by muse, mutect2, varscan2
- DYNC1H1 | c.10518C>T p.D3506= | Silent (SNP) | VAF 152/436 reads (35%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13278C>T p.D4426= | Silent (SNP) | VAF 43/302 reads (14%) | catalogued as rs777098264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYRK1B | c.1167G>A p.R389= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- DZIP1 | c.259C>T p.L87= | Silent (SNP) | VAF 14/261 reads (5%) | called by muse, mutect2
- EPHX2 | c.1077T>C p.N359= | Silent (SNP) | VAF 14/165 reads (8%) | called by muse, mutect2
- EXOC8 | c.234C>T p.S78= | Silent (SNP) | VAF 22/390 reads (6%) | catalogued as rs1359130552; called by muse, mutect2
- FAM187B | c.513T>A p.P171= | Silent (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- FGR | c.1005G>A p.E335= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2
- FOCAD | c.5382A>G p.V1794= | Silent (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 49/114 reads (43%) | called by muse, mutect2, varscan2
- GAS2L3 | c.405T>C p.I135= | Silent (SNP) | VAF 75/226 reads (33%) | called by muse, mutect2, varscan2
- GJC2 | c.990G>A p.P330= | Silent (SNP) | VAF 15/350 reads (4%) | called by muse, mutect2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 84/433 reads (19%) | called by muse, mutect2, varscan2
- GPR6 | c.552C>T p.G184= | Silent (SNP) | VAF 28/386 reads (7%) | catalogued as rs749724115; called by muse, mutect2
- GUK1 | c.345G>A p.L115= | Silent (SNP) | VAF 32/536 reads (6%) | called by muse, mutect2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 74/192 reads (39%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 106/249 reads (43%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HCRTR1 | c.615C>T p.R205= | Silent (SNP) | VAF 70/165 reads (42%) | called by muse, mutect2, varscan2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 68/148 reads (46%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HEPACAM | c.381C>T p.T127= | Silent (SNP) | VAF 56/286 reads (20%) | catalogued as rs766390439, COSV53432420; called by muse, mutect2, varscan2
- HOXD9 | c.898C>T p.L300= | Silent (SNP) | VAF 88/205 reads (43%) | called by muse, mutect2, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 118/332 reads (36%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IBTK | c.2991C>T p.N997= | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 110/267 reads (41%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 59/154 reads (38%) | called by muse, mutect2, varscan2
- KCNJ16 | c.630C>T p.H210= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as rs199847474; called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 106/380 reads (28%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KDM6B | c.2851C>A p.R951= | Silent (SNP) | VAF 30/202 reads (15%) | called by muse, mutect2, varscan2
- KIZ | c.1248T>C p.A416= | Silent (SNP) | VAF 19/193 reads (10%) | called by muse, mutect2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 69/145 reads (48%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- KRT39 | c.315G>A p.E105= | Silent (SNP) | VAF 109/280 reads (39%) | catalogued as COSV100842175; called by muse, mutect2, varscan2
- KRT6A | c.592C>T p.L198= | Silent (SNP) | VAF 106/750 reads (14%) | catalogued as rs1398015289; called by muse, mutect2, varscan2
- LHX2 | c.1014C>T p.D338= | Silent (SNP) | VAF 14/226 reads (6%) | catalogued as rs776746832; called by muse, mutect2
- LRWD1 | c.1596C>G p.G532= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as rs1195603578; called by muse, mutect2, varscan2
- LTBP2 | c.2856C>T p.Y952= | Silent (SNP) | VAF 220/554 reads (40%) | called by muse, mutect2, varscan2
- LZTR1 | c.1425G>A p.T475= | Silent (SNP) | VAF 40/234 reads (17%) | catalogued as rs140414846; called by muse, mutect2, varscan2
- MAP2 | c.1566C>T p.T522= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs1202899945, COSV52286814; called by muse, mutect2, varscan2
- MAST4 | c.4398C>T p.H1466= (on ENST00000403625 / NM_001164664.2; = p.H1277= on NM_015183.3) | Silent (SNP) | VAF 111/261 reads (43%) | called by muse, mutect2, varscan2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 52/139 reads (37%) | called by muse, mutect2, varscan2
- MVB12B | c.690C>A p.T230= | Silent (SNP) | VAF 8/231 reads (3%) | called by muse, mutect2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NKX2-5 | c.300C>T p.P100= | Silent (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- NPAS3 | c.2076G>A p.P692= (on ENST00000356141 / NM_001164749.2; = p.P660= on NM_022123.3) | Silent (SNP) | VAF 68/176 reads (39%) | catalogued as rs1295093051, COSV60840889; called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 170/478 reads (36%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- OR2V2 | c.63C>T p.H21= | Silent (SNP) | VAF 88/200 reads (44%) | called by muse, mutect2
- OR3A3 | c.408C>T p.C136= | Silent (SNP) | VAF 44/309 reads (14%) | catalogued as COSV52166789; called by muse, mutect2, varscan2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 134/402 reads (33%) | catalogued as rs1340855486, COSV55505013; called by muse, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- PAK6 | c.141G>A p.L47= | Silent (SNP) | VAF 88/203 reads (43%) | called by muse, mutect2, varscan2
- PAOX | c.1116C>A p.A372= | Silent (SNP) | VAF 64/173 reads (37%) | catalogued as COSV53370990, COSV53372538; called by muse, mutect2, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 128/317 reads (40%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1665C>T p.N555= | Silent (SNP) | VAF 129/407 reads (32%) | called by muse, mutect2, varscan2
- PHF23 | c.366C>A p.P122= | Silent (SNP) | VAF 87/234 reads (37%) | catalogued as COSV50038138; called by muse, mutect2, varscan2
- PICK1 | c.1161G>A p.E387= | Silent (SNP) | VAF 69/198 reads (35%) | catalogued as rs1266755272; called by mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PITRM1 | c.423T>C p.S141= | Silent (SNP) | VAF 6/145 reads (4%) | called by muse, mutect2
- PKD2 | c.180G>A p.R60= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs1263674695; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEC | c.12642C>T p.N4214= (on ENST00000322810 / NM_201380.4; = p.N4104= on NM_000445.5) | Silent (SNP) | VAF 198/444 reads (45%) | catalogued as rs140538836, COSV59653873; called by muse, mutect2, varscan2
- PLEKHA6 | c.2760T>C p.T920= | Silent (SNP) | VAF 26/342 reads (8%) | called by muse, mutect2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 159/328 reads (48%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- POPDC2 | c.789C>T p.R263= | Silent (SNP) | VAF 102/242 reads (42%) | catalogued as rs1283131215; called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- PPP1R3A | c.2982C>T p.G994= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- PRR14L | c.4794C>T p.C1598= | Silent (SNP) | VAF 38/171 reads (22%) | called by muse, mutect2, varscan2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 64/268 reads (24%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2, varscan2
- PTCH1 | c.3360G>A p.E1120= | Silent (SNP) | VAF 183/410 reads (45%) | catalogued as rs1554690458; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTCH2 | c.3270G>T p.A1090= | Silent (SNP) | VAF 24/372 reads (6%) | called by muse, mutect2
- PTPN18 | c.1146C>T p.S382= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- RALBP1 | c.900G>A p.V300= | Silent (SNP) | VAF 81/197 reads (41%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 69/185 reads (37%) | called by muse, mutect2, varscan2
- RBM15 | c.1221G>A p.R407= | Silent (SNP) | VAF 90/239 reads (38%) | catalogued as rs777680641; called by muse, mutect2, varscan2
- RELN | c.4194G>A p.V1398= | Silent (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- RPS6KA4 | c.2046G>A p.S682= | Silent (SNP) | VAF 21/246 reads (9%) | called by muse, mutect2
- RTP5 | c.183G>A p.G61= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as COSV58320097; called by muse, mutect2, varscan2
- SETBP1 | c.819G>A p.T273= | Silent (SNP) | VAF 114/268 reads (43%) | catalogued as rs772700161, COSV56336632; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 218/552 reads (39%) | called by muse, varscan2
- SIPA1L1 | c.4056A>G p.S1352= | Silent (SNP) | VAF 68/399 reads (17%) | called by muse, mutect2, varscan2
- SLC22A9 | c.1249C>T p.L417= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs1478775618; called by muse, mutect2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 73/187 reads (39%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SNAP23 | c.255C>T p.C85= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- SPEG | c.3678C>T p.H1226= | Silent (SNP) | VAF 183/312 reads (59%) | catalogued as rs1388099213; called by muse, mutect2, varscan2
- SPTBN5 | c.8577C>T p.C2859= | Silent (SNP) | VAF 17/185 reads (9%) | called by muse, mutect2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- STRA6 | c.417T>C p.T139= | Silent (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 126/320 reads (39%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TECTA | c.285C>T p.F95= | Silent (SNP) | VAF 104/243 reads (43%) | catalogued as rs775584376, COSV50817729; called by muse, mutect2, varscan2
- TEX38 | c.216A>C p.R72= | Silent (SNP) | VAF 74/183 reads (40%) | called by muse, mutect2, varscan2
- TFAP2B | c.534C>T p.D178= | Silent (SNP) | VAF 24/317 reads (8%) | catalogued as COSV53832073; called by muse, mutect2
- TFRC | c.2094A>G p.R698= | Silent (SNP) | VAF 92/235 reads (39%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1866G>A p.R622= | Silent (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- TOR1A | c.717G>A p.A239= | Silent (SNP) | VAF 26/518 reads (5%) | catalogued as rs549781734; called by muse, mutect2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 95/181 reads (52%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRNAU1AP | c.849C>A p.I283= | Silent (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.73296A>G p.V24432= (on ENST00000591111; = p.V17008= on NM_003319.4) | Silent (SNP) | VAF 77/232 reads (33%) | catalogued as rs761647014; called by muse, mutect2, varscan2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 198/452 reads (44%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 67/326 reads (21%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- VEGFD | c.438C>T p.C146= | Silent (SNP) | VAF 78/164 reads (48%) | called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 169/370 reads (46%) | called by muse, mutect2, varscan2
- VPS18 | c.1173G>A p.V391= | Silent (SNP) | VAF 26/319 reads (8%) | called by muse, mutect2
- WDR62 | c.966C>A p.A322= | Silent (SNP) | VAF 22/292 reads (8%) | called by muse, mutect2
- WDR90 | c.2143C>T p.L715= | Silent (SNP) | VAF 146/392 reads (37%) | called by muse, mutect2, varscan2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- ZNF850 | c.723T>C p.I241= | Silent (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- AC068587.7 | n.128G>T | RNA (SNP) | VAF 19/374 reads (5%) | called by muse, mutect2
- AC099548.2 | n.1288del | RNA (DEL) | VAF 12/89 reads (13%) | called by mutect2, varscan2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 44/129 reads (34%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14097C>T | Intron (SNP) | VAF 82/179 reads (46%) | catalogued as rs1190788629; called by muse, mutect2, varscan2
- ADAM1A | n.1368C>T | RNA (SNP) | VAF 93/236 reads (39%) | called by muse, mutect2, varscan2
- AK9 | c.1254+19_1254+22del | Intron (DEL) | VAF 3/34 reads (9%) | catalogued as rs770626634; called by pindel, varscan2*
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 191/956 reads (20%) | called by muse, varscan2
- ARHGEF15 | c.601+23G>A | Intron (SNP) | VAF 14/208 reads (7%) | catalogued as rs1397138771; called by muse, mutect2
- ARHGEF25 | chr12:57620943 G>A | 3'Flank (SNP) | VAF 141/390 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11575C>A | Intron (SNP) | VAF 47/160 reads (29%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- B3GALNT2 | c.113-1407G>A | Intron (SNP) | VAF 17/52 reads (33%) | catalogued as rs1383985581; called by muse, mutect2
- CACNB1 | c.1332+23G>A | Intron (SNP) | VAF 81/203 reads (40%) | called by muse, mutect2, varscan2
- CASP10 | c.685-3268dup | Intron (INS) | VAF 43/164 reads (26%) | called by mutect2, varscan2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- CFAP52 | c.71-1461G>A | Intron (SNP) | VAF 17/64 reads (27%) | catalogued as rs867168009; called by muse, mutect2, varscan2
- COQ8A | c.*34A>T | 3'UTR (SNP) | VAF 85/413 reads (21%) | called by muse, mutect2, varscan2
- CTDSP1 | c.67+557G>A | Intron (SNP) | VAF 114/338 reads (34%) | catalogued as rs910857141; called by muse, mutect2, varscan2
- DCHS2 | n.1644G>A | RNA (SNP) | VAF 17/224 reads (8%) | called by muse, mutect2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 135/378 reads (36%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 81/226 reads (36%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-45T>G | Intron (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 24/65 reads (37%) | catalogued as rs1446348498; called by mutect2, pindel, varscan2
- EMC10 | c.679-266C>G | Intron (SNP) | VAF 46/127 reads (36%) | catalogued as rs779918120, COSV58541974; called by muse, mutect2, varscan2
- ENAH | c.803-282del | Intron (DEL) | VAF 40/249 reads (16%) | called by mutect2, pindel, varscan2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 48/123 reads (39%) | called by muse, mutect2, varscan2
- FAS | c.*589C>T | 3'UTR (SNP) | VAF 38/152 reads (25%) | called by muse, mutect2, varscan2
- GLYCTK | c.-47G>C | 5'UTR (SNP) | VAF 54/126 reads (43%) | called by muse, mutect2, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 78/188 reads (41%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- HERC2P2 | n.2833C>T | RNA (SNP) | VAF 48/526 reads (9%) | catalogued as rs748325093; called by muse, mutect2
- HERC2P3 | n.768G>A | RNA (SNP) | VAF 53/312 reads (17%) | catalogued as rs761831955; called by muse, mutect2, varscan2
- HEXD | c.*44del | 3'UTR (DEL) | VAF 95/245 reads (39%) | catalogued as rs751615819; called by mutect2, pindel, varscan2
- IKZF1 | c.161-8322del | Intron (DEL) | VAF 21/184 reads (11%) | called by mutect2, pindel, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- KDM4C | c.2994+116del | Intron (DEL) | VAF 54/134 reads (40%) | catalogued as COSV67183745; called by mutect2, varscan2
- KRT8P11 | n.1365G>A | RNA (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- L3MBTL1 | c.1193-30C>T | Intron (SNP) | VAF 67/206 reads (33%) | catalogued as rs374464014; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331751 ins C | 5'Flank (INS) | VAF 31/171 reads (18%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 63/170 reads (37%) | called by muse, mutect2, varscan2
- MAPRE3 | c.267+106G>A | Intron (SNP) | VAF 18/54 reads (33%) | catalogued as rs767804788; called by muse, varscan2
- MDFIC | c.-7G>A | 5'UTR (SNP) | VAF 91/207 reads (44%) | catalogued as rs930922489; called by muse, mutect2, varscan2
- MORC2 | chr22:30922485 G>A | 3'Flank (SNP) | VAF 28/289 reads (10%) | called by muse, mutect2
- MS4A6A | c.651+10C>T | Intron (SNP) | VAF 101/213 reads (47%) | called by muse, mutect2, varscan2
- MTSS1 | c.1404+38T>C | Intron (SNP) | VAF 11/268 reads (4%) | called by muse, mutect2
- MUC19 | chr12:40421242 del A | 3'Flank (DEL) | VAF 4/12 reads (33%) | catalogued as rs746639059; called by mutect2, varscan2
- MUC19 | c.271-7del | Intron (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 72/300 reads (24%) | catalogued as rs1305952989, COSV58516256; called by muse, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 40/110 reads (36%) | catalogued as rs1349876274; called by mutect2, varscan2
- NLRC5 | c.4154+205G>T | Intron (SNP) | VAF 47/142 reads (33%) | catalogued as rs1295311548; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 33/71 reads (46%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- ODAPH | c.*38del | 3'UTR (DEL) | VAF 39/238 reads (16%) | catalogued as rs763292297; called by mutect2, varscan2
- OGFOD1 | c.301-20del | Intron (DEL) | VAF 34/66 reads (52%) | catalogued as rs771823733; called by mutect2, varscan2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 193/556 reads (35%) | called by mutect2, pindel, varscan2
- PCSK4 | c.1391+15C>T | Intron (SNP) | VAF 49/123 reads (40%) | catalogued as rs539574874; called by muse, mutect2, varscan2
- PDPK1 | c.1344-2653G>A | Intron (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- PHYKPL | c.59+17C>T | Intron (SNP) | VAF 41/119 reads (34%) | catalogued as rs749198645; called by muse, mutect2, varscan2
- PI4KAP2 | n.2831C>A | RNA (SNP) | VAF 59/156 reads (38%) | called by muse, mutect2, varscan2
- PITRM1 | c.2646-904C>T | Intron (SNP) | VAF 32/124 reads (26%) | catalogued as rs919528512; called by muse, mutect2, varscan2
- PKD1L2 | n.270C>T | RNA (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- POLM | c.714+75C>A | Intron (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- POPDC2 | c.1009+84del | Intron (DEL) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- POU2F2 | c.303+365G>T | Intron (SNP) | VAF 22/112 reads (20%) | catalogued as rs368244459; called by muse, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 112/248 reads (45%) | called by muse, varscan2
- PRRC2C | c.8199+1071G>A | Intron (SNP) | VAF 82/386 reads (21%) | called by muse, mutect2, varscan2
- PUS10 | c.126+907C>T | Intron (SNP) | VAF 49/114 reads (43%) | called by muse, mutect2, varscan2
- RAB26 | c.307-380T>G | Intron (SNP) | VAF 59/168 reads (35%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991892 G>A | 3'Flank (SNP) | VAF 61/150 reads (41%) | called by muse, mutect2, varscan2
- RNF220 | c.1630-10C>G | Intron (SNP) | VAF 27/255 reads (11%) | called by muse, mutect2, varscan2
- RPL28 | c.205+160_205+162del | Intron (DEL) | VAF 44/122 reads (36%) | catalogued as rs750063282; called by mutect2, pindel, varscan2
- RPS15 | c.90-32G>A | Intron (SNP) | VAF 62/397 reads (16%) | called by muse, varscan2
- SCN4B | c.*317G>A | 3'UTR (SNP) | VAF 181/460 reads (39%) | catalogued as rs1431822176; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837959 C>T | 3'Flank (SNP) | VAF 74/403 reads (18%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 60/292 reads (21%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SNW1 | c.1413-30T>A | Intron (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 39/117 reads (33%) | called by mutect2, pindel, varscan2
- STAB1 | c.4364-40del | Intron (DEL) | VAF 31/89 reads (35%) | called by mutect2, pindel, varscan2
- TPRXL | n.752C>T | RNA (SNP) | VAF 40/224 reads (18%) | catalogued as rs192562800; called by muse, varscan2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 44/113 reads (39%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- ZDHHC23 | c.1217-20del | Intron (DEL) | VAF 16/46 reads (35%) | catalogued as rs767083235; called by mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 14/80 reads (18%) | catalogued as rs751858242; called by mutect2, varscan2
- ZNF252P | n.245+3153del | Intron (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- ZRANB3 | c.1206+399del | Intron (DEL) | VAF 42/122 reads (34%) | called by mutect2, pindel, varscan2
- ZYG11B | c.-26G>A | 5'UTR (SNP) | VAF 7/195 reads (4%) | called by muse, mutect2
